Gene-level copy-number profile of tumor specimen SM-JU34N from CPTAC case C207624, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU34N: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78a1fb11-cea3-40cb-bf3d-fd13c4aff5f1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105207 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/c6e8f09e-bfdd-4af0-a826-69be63514698

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 918; copy number 2: 14,805; copy number 3: 34,272; copy number 4: 6,112; copy number 5: 2,271; copy number 6: 8.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.
- chr10:87,751,512–87,863,533, 4 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene (within-gene range 0–2): AC063965.2.
- chr14:18,692,032–18,699,978, 2 genes: RPL22P20, CR383656.4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 918. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
